Gene-level copy-number profile of tumor specimen TCGA-46-3768-01A from TCGA case TCGA-46-3768, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 58.3 years (21,307 days).
Specimen TCGA-46-3768-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.d0f1f6bb-2302-48c8-b3bb-e21b4508faaf.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-46-3768-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a2a880ff-63e3-47db-ac07-140cf0fdd921

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 36; copy number 1: 3; copy number 2: 1,685; copy number 3: 20,998; copy number 4: 10,197; copy number 5: 18,763; copy number 6: 4,751; copy number 7: 1,030; copy number 8: 1,178; copy number 9: 73; copy number 10: 200; copy number 11: 187; copy number 13: 118; copy number 16: 138; copy number 17: 458.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-46-3768-01A-01D-0978-01): tumor purity 0.75, ploidy 3.41, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 36 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:140,992,543–140,992,659, 1 gene: Y_RNA.
- chr9:19,789,179–20,622,499, 11 genes (within-gene range 0–3): AL158077.2, AL158077.1, AL591222.1, AL591222.2, AL591222.3, AL512635.1, MLLT3, MIR4473, RNU4-26P, MIR4474, AL163193.1.
- chr9:20,683,304–20,716,188, 2 genes: FOCAD-AS1, MIR491.
- chr9:21,638,285–22,824,213, 20 genes: H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239.
- chr9:22,747,700–22,768,316, 2 genes: CLIC4P1, AC017067.1.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 901 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:109,129,205–109,504,634, 1 gene, copy number 13 (within-gene range 10–13): SH3RF3.
- chr2:109,251,422–110,716,595, 49 genes, copy number 13: SNRPGP9, MIR4266, SEPTIN10, RPL37P12, AC011753.2, SOWAHC, AC011753.1, BMS1P19, SRSF3P6, RPL22P11, AC074387.1, RGPD5, LIMS3, AC013271.1, AC013268.1, AC013268.5, GPAA1P1, ZBTB45P1, LINC01123, AC013268.3, AC013268.2, AC013268.4, MIR4267, MALL, MIR4436B1, NPHP1, ACTR1AP1, MTLN, AC140479.3, AC140479.4, MALLP1, MIR4436B2, AC140479.5, AC140479.1, AC140479.2, LINC01106, ZBTB45P2, GPAA1P2, AC112229.4, AC112229.1, AC112229.3, LIMS4, AC112229.2, AC108938.1, RGPD6, AC226101.1, RPL22P12, BUB1, AC114776.1.
- chr3:85,992,183–95,172,377, 57 genes, copy number 13 (within-gene range 2–13): CADM2-AS1, THAP12P2, AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6, AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P, HSPE1P19, ABBA01000933.1, ABBA01000935.2, RNU6-488P, PROS1, Y_RNA, RNU6-511P, ARL13B, HMGN1P7, STX19, DHFR2, NSUN3, RBBP4P2, ARMC10P1, AC140059.1, WDR82P1, LINC00879, RPS18P6.
- chr3:96,244,732–97,752,460, 11 genes, copy number 13 (within-gene range 8–13): AC107304.1, HNRNPKP4, MIR8060, AC107015.1, RNU6-1094P, MTRNR2L12, RPL18AP8, RCC2P5, CDV3P1, AC109782.1, EPHA6.
- chr3:162,486,541–198,222,513, 645 genes, copy number 11–17 (broad region; genes not listed).
- chr9:34,179,005–37,034,268, 126 genes, copy number 16 (within-gene range 5–16) (broad region; genes not listed).
- chr17:20,008,051–20,403,557, 12 genes, copy number 16 (within-gene range 5–16): AC005730.2, SPECC1, AC005730.1, KCTD9P1, RNU6-258P, AC004702.1, RNU6-1057P, CCDC144CP, RNU6-467P, AC008088.1, Metazoa_SRP, UPF3AP2.

Autosomal genes at a single copy (total copy number 1): 3. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
